Somatic mutation profile of tumor specimen C3N-01522-01 (aliquot CPT0077110009) from CPTAC case C3N-01522, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.4 years (29,350 days).
Specimen C3N-01522-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd790c16-e37c-43ee-82c4-81515941cae1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01522-71 (Blood Derived Normal), aliquot CPT0077230002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fa52c3a-999e-4bb7-a8ec-5ceb76d9ef97

The open-access MAF lists 100 somatic variants for this specimen: 66 protein-altering or splice-affecting, 24 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 24, Frame Shift Del 10, Nonsense Mutation 9, Intron 6, 3'UTR 3, Splice Site 3, Frame Shift Ins 2, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3203C>T p.S1068L | Missense Mutation (SNP) | VAF 106/368 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.024); catalogued as CD160909, CM023010, COSV57330367, COSV57359180; called by muse, mutect2, varscan2
- CKAP5 | c.2719G>T p.G907C | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.739); catalogued as COSV56367654; called by mutect2, varscan2
- CTAGE1 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 42/213 reads (20%) | catalogued as COSV101194675; called by muse, mutect2, varscan2
- CYP26A1 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs754813478; called by muse, mutect2, varscan2
- GAS2L2 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs370992265; called by muse, mutect2, varscan2
- GBP3 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as COSV52519257; called by muse, mutect2, varscan2
- HECW1 | c.3937G>T p.G1313* | Nonsense Mutation (SNP) | VAF 83/230 reads (36%) | catalogued as COSV67835255; called by muse, mutect2, varscan2
- KDM5C | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 156/232 reads (67%) | catalogued as CM061210, COSV64763470; called by muse, mutect2, varscan2
- KIAA2013 | c.422T>G p.V141G | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs1307752691; called by muse, mutect2, varscan2
- LRP1 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 194/610 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs769851229, COSV54507646; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAGEC3 | c.1813A>G p.M605V | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs200784001; called by muse, mutect2, varscan2
- MMP17 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs769408097, COSV100861946; called by muse, mutect2, varscan2
- MROH2A | c.2306C>G p.P769R | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1025990760; called by muse, mutect2, varscan2
- MROH5 | c.2095C>T p.Q699* | Nonsense Mutation (SNP) | VAF 52/153 reads (34%) | catalogued as rs1385014722; called by muse, mutect2, varscan2
- OR5J2 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 88/240 reads (37%) | catalogued as COSV100399225; called by muse, mutect2, varscan2
- PBRM1 | c.673A>T p.K225* | Nonsense Mutation (SNP) | VAF 30/59 reads (51%) | catalogued as COSV56277528; called by muse, mutect2, varscan2
- PITPNM3 | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 160/530 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs373601000; called by muse, mutect2, varscan2
- PLA2G7 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 116/413 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs928438839; called by muse, mutect2, varscan2
- PPWD1 | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV54333546; called by muse, mutect2, varscan2
- RBBP9 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 82/247 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as rs775738842; called by muse, mutect2, varscan2
- SLITRK6 | c.2135G>A p.S712N | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1438568169; called by muse, mutect2, varscan2
- SPTBN2 | c.6343G>A p.G2115S | Missense Mutation (SNP) | VAF 232/671 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs200435710; called by muse, mutect2, varscan2
- SYNPO2 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 20/121 reads (17%) | catalogued as COSV61113779; called by muse, mutect2, varscan2
- TEDDM1 | c.819del p.*274Efs*37 | Frame Shift Del (DEL) | VAF 52/164 reads (32%) | catalogued as rs759664603; called by mutect2, pindel, varscan2
- TMEM108 | c.166A>G p.S56G | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as rs1303009645; called by muse, mutect2, varscan2
- ABCC3 | c.1635+1G>A p.X545_splice | Splice Site (SNP) | VAF 124/373 reads (33%) | called by muse, mutect2, varscan2
- ADGRF1 | c.307T>C p.C103R | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMPH | c.932del p.P311Rfs*24 | Frame Shift Del (DEL) | VAF 91/299 reads (30%) | called by mutect2, pindel, varscan2
- ANHX | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2
- ATP13A1 | c.3416C>A p.A1139E | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- C5orf24 | c.365del p.P122Qfs*46 | Frame Shift Del (DEL) | VAF 178/562 reads (32%) | called by mutect2, pindel, varscan2
- CEACAM21 | c.227_245del p.N76Mfs*2 | Frame Shift Del (DEL) | VAF 117/465 reads (25%) | called by mutect2, pindel, varscan2
- CHD6 | c.2629T>C p.F877L | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CMBL | c.467-1G>C p.X156_splice | Splice Site (SNP) | VAF 52/140 reads (37%) | called by muse, mutect2, varscan2
- CYYR1 | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- EXOC2 | c.50A>C p.E17A | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FAM227A | c.1129C>A p.H377N | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- GFPT2 | c.1278G>C p.E426D | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- KLHL30 | c.1587C>A p.Y529* | Nonsense Mutation (SNP) | VAF 124/394 reads (31%) | called by muse, mutect2, varscan2
- LMO7 | c.4657C>G p.P1553A (on ENST00000357063; = p.P1234A on NM_005358.5) | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MAP3K21 | c.1105T>A p.C369S | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MPND | c.1048A>G p.S350G | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTRF1 | c.815T>C p.M272T | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- MYMK | c.509T>G p.F170C | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- NAALADL1 | c.2174_2175del p.T725Sfs*14 | Frame Shift Del (DEL) | VAF 41/144 reads (28%) | called by mutect2, pindel, varscan2
- NEB | c.4348A>T p.I1450F | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NSD1 | c.2204C>A p.A735E | Missense Mutation (SNP) | VAF 128/465 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52H1 | c.423G>C p.K141N (on ENST00000322653; = p.K147N on NM_001005289.1) | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PAFAH2 | c.584T>C p.V195A | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- PCED1A | c.821C>G p.P274R | Missense Mutation (SNP) | VAF 118/307 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PER3 | c.2295del p.N766Tfs*83 | Frame Shift Del (DEL) | VAF 54/189 reads (29%) | called by mutect2, pindel, varscan2
- PRR33 | c.64G>T p.G22* | Nonsense Mutation (SNP) | VAF 89/236 reads (38%) | called by muse, mutect2, varscan2
- RBL2 | c.602T>G p.F201C | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- RBM4B | c.349_350insT p.H117Lfs*16 | Frame Shift Ins (INS) | VAF 45/168 reads (27%) | called by mutect2, pindel*, varscan2
- RIC8A | c.1065+2T>C p.X355_splice | Splice Site (SNP) | VAF 119/328 reads (36%) | called by muse, mutect2, varscan2
- ROCK2 | c.3176A>C p.K1059T | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SCCPDH | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SETD2 | c.887del p.S296Lfs*5 | Frame Shift Del (DEL) | VAF 25/45 reads (56%) | called by mutect2, pindel, varscan2
- SLC22A12 | c.1045del p.R349Gfs*52 | Frame Shift Del (DEL) | VAF 148/517 reads (29%) | called by mutect2, pindel, varscan2
- SLCO1C1 | c.1888T>G p.C630G | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCEA2 | c.800dup p.N268Efs*13 | Frame Shift Ins (INS) | VAF 28/118 reads (24%) | called by mutect2, pindel
- TDRD12 | c.296A>T p.K99M | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TMTC1 | c.2228T>A p.I743N (on ENST00000539277 / NM_001193451.2; = p.I635N on NM_175861.3) | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TRIM49D1 | c.1027del p.W343Gfs*67 | Frame Shift Del (DEL) | VAF 63/477 reads (13%) | called by mutect2, pindel, varscan2
- TRPV5 | c.1592T>A p.F531Y | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- ZXDC | c.2546del p.G849Efs*24 | Frame Shift Del (DEL) | VAF 108/330 reads (33%) | called by mutect2, pindel, varscan2
- ABHD3 | c.108T>A p.L36= | Silent (SNP) | VAF 29/157 reads (18%) | called by muse, mutect2, varscan2
- ATP11B | c.1230T>C p.G410= | Silent (SNP) | VAF 46/109 reads (42%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.291T>A p.P97= | Silent (SNP) | VAF 130/407 reads (32%) | called by muse, mutect2, varscan2
- EMSY | c.153A>G p.E51= | Silent (SNP) | VAF 32/110 reads (29%) | called by muse, mutect2
- FNIP2 | c.1905G>A p.G635= | Silent (SNP) | VAF 62/227 reads (27%) | called by muse, mutect2, varscan2
- HNRNPF | c.273C>T p.T91= | Silent (SNP) | VAF 34/176 reads (19%) | catalogued as rs899239899, COSV61560762; called by muse, mutect2, varscan2
- IFT172 | c.4383G>A p.Q1461= | Silent (SNP) | VAF 66/231 reads (29%) | catalogued as COSV53137617; called by muse, mutect2, varscan2
- ITLN1 | c.105A>C p.P35= | Silent (SNP) | VAF 58/247 reads (23%) | called by muse, mutect2, varscan2
- LIPA | c.171T>C p.D57= | Silent (SNP) | VAF 55/213 reads (26%) | called by muse, mutect2, varscan2
- NCCRP1 | c.54G>A p.G18= | Silent (SNP) | VAF 134/456 reads (29%) | catalogued as rs753673551; called by muse, mutect2, varscan2
- OR2V1 | c.801G>C p.R267= | Silent (SNP) | VAF 38/99 reads (38%) | called by muse, mutect2, varscan2
- OR2Z1 | c.312C>A p.L104= | Silent (SNP) | VAF 83/265 reads (31%) | catalogued as COSV100136454; called by muse, mutect2, varscan2
- OR5P3 | c.12A>G p.G4= | Silent (SNP) | VAF 13/30 reads (43%) | called by muse, varscan2
- ORMDL2 | c.129C>T p.F43= | Silent (SNP) | VAF 58/204 reads (28%) | called by muse, mutect2, varscan2
- PARP6 | c.402G>C p.L134= | Silent (SNP) | VAF 11/164 reads (7%) | called by muse, mutect2
- PEX5L | c.114A>G p.A38= | Silent (SNP) | VAF 60/215 reads (28%) | called by muse, mutect2, varscan2
- PRR14 | c.1272A>G p.P424= | Silent (SNP) | VAF 86/284 reads (30%) | called by muse, mutect2, varscan2
- RAET1E | c.198T>C p.S66= | Silent (SNP) | VAF 105/189 reads (56%) | called by muse, mutect2, varscan2
- SLC25A30 | c.627C>G p.T209= | Silent (SNP) | VAF 55/151 reads (36%) | called by muse, mutect2, varscan2
- SNX11 | c.18G>A p.R6= | Silent (SNP) | VAF 62/236 reads (26%) | catalogued as rs772748470; called by muse, mutect2, varscan2
- TTN | c.48192A>G p.V16064= (on ENST00000591111; = p.V8640= on NM_003319.4) | Silent (SNP) | VAF 192/596 reads (32%) | catalogued as rs1182402471; called by muse, mutect2, varscan2
- UGCG | c.795A>G p.S265= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as rs757865261; called by muse, mutect2, varscan2
- ZNF343 | c.1621A>C p.R541= | Silent (SNP) | VAF 122/311 reads (39%) | catalogued as rs769462325; called by muse, mutect2, varscan2
- ZXDA | c.2115G>A p.L705= | Silent (SNP) | VAF 68/125 reads (54%) | called by muse, mutect2, varscan2
- APTX | c.-149G>A | 5'UTR (SNP) | VAF 136/455 reads (30%) | catalogued as rs564001060; called by muse, mutect2, varscan2
- COLEC11 | c.*67A>T | 3'UTR (SNP) | VAF 140/407 reads (34%) | called by muse, mutect2, varscan2
- CSNK1D | c.737-51T>A | Intron (SNP) | VAF 153/406 reads (38%) | called by muse, mutect2, varscan2
- GTPBP8 | c.336+194C>T | Intron (SNP) | VAF 48/148 reads (32%) | called by muse, mutect2, varscan2
- KIAA0100 | c.516-16T>A | Intron (SNP) | VAF 54/155 reads (35%) | called by muse, mutect2, varscan2
- MTHFR | c.475+9C>A | Intron (SNP) | VAF 104/304 reads (34%) | called by muse, mutect2, varscan2
- MTPN | c.*2197A>T | 3'UTR (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- NOL3 | c.-8-245G>A | Intron (SNP) | VAF 102/272 reads (38%) | called by muse, mutect2, varscan2
- PDE4DIP | c.*52A>T | 3'UTR (SNP) | VAF 122/480 reads (25%) | called by muse, mutect2, varscan2
- PDE6B | c.1060-39G>A | Intron (SNP) | VAF 69/205 reads (34%) | catalogued as rs369121532; called by muse, mutect2, varscan2
